Surgical pathology report (de-identified scan), TCGA case TCGA-76-4935, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4935-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left parietal occipital brain tumor (excision): glioblastoma, grade IV of IV (WHO scale), see microscopic description, see comment.

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic, densely cellular, and infiltrative proliferation of astrocytes. There are numerous mitoses as well as foci of pseudopalisading necrosis. Microvascular proliferation is present. The findings are diagnostic of a glioblastoma, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

1. Left parietal occipital tumor: Glioblastoma. [REDACTED]

Clinical History and Diagnosis:
glioma

Source of Specimen:

- 1: Left parietal occipital tumor

[page 2 of 2]
[REDACTED]

Gross Description:

[REDACTED]

1. Left parietal occipital tumor: T. fresh for frozen section in specimen container labeled with the patient's name and "#1 left parietal occipital tumor consistent with glioma", a 1.5 x 1.0 x 0.5 cm portion of tan-pink soft tissue. Touch preparations are made and approximately 50% of the specimen is made for frozen section analysis. The remainder of the specimen is entirely submitted for a total of 2 cassettes.

A. frozen section control

B. remainder of specimen

Histology Laboratory

H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED] Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 309b44ba-d650-4b9b-9c85-127c4df646b2 (TCGA-76-4935.84580AE3-E984-4071-B9CE-1641F06963AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).